Somatic mutation profile of tumor specimen ALCH-B389-TTP1-A (aliquot ALCH-B389-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B389, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.5 years (23,565 days).
Specimen ALCH-B389-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0723917-7276-4468-ad12-8c66a04dc737.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B389-NB1-A (Blood Derived Normal), aliquot ALCH-B389-NB1-A-1-1-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cbabe8e-6cca-423d-8aad-6bebe122db99

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 4, Intron 1, Frame Shift Ins 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/485 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- ACAN | c.871C>A p.Q291K | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.146); catalogued as COSV100718247; called by muse, mutect2
- APOB | c.4481C>T p.S1494L | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1020402380, COSV51922665; ClinVar: uncertain significance; called by muse, mutect2
- DMD | c.2135G>T p.R712M | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55872046, COSV55908806; called by muse, mutect2
- MANEAL | c.974A>G p.Y325C (on ENST00000373045 / NM_001113482.1; = p.Y103C on NM_152496.2) | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763727097; called by muse, mutect2
- MPV17L2 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1478146134; called by muse, mutect2, varscan2
- SERPINB3 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 55/544 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52193727; called by muse, mutect2
- SMIM10 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.883); catalogued as COSV57707582; called by muse, mutect2
- ADAMTS3 | c.3267G>T p.L1089F | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); called by muse, mutect2
- ALG1 | c.901+3A>T | Splice Region (SNP) | VAF 33/505 reads (7%) | called by muse, mutect2
- CBWD2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 34/904 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- CCDC149 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- CNKSR1 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- COL6A5 | c.2094G>A p.M698I | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.955); called by muse, mutect2
- DSC3 | c.860A>T p.Q287L | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNIP3 | c.405C>G p.F135L | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- KLF11 | c.1330C>T p.H444Y | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP1B | c.8497G>A p.G2833S | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MITF | c.1399C>A p.P467T (on ENST00000448226 / NM_006722.3; = p.P367T on NM_000248.4) | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- NSD3 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); called by muse, mutect2
- RTN4 | c.839C>G p.A280G | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- SETD2 | c.4175dup p.N1392Kfs*6 | Frame Shift Ins (INS) | VAF 10/97 reads (10%) | called by mutect2, pindel
- THBS3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.114); called by muse, mutect2
- VWDE | c.3946T>A p.C1316S | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- XIRP2 | c.6392T>A p.I2131N (on ENST00000628543; = p.I2306N on NM_152381.6) | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- EIF2B4 | c.996G>A p.V332= (on ENST00000347454 / NM_001034116.2; = p.V331= on NM_015636.3) | Silent (SNP) | VAF 55/539 reads (10%) | called by muse, mutect2, varscan2
- KCNA4 | c.1671A>G p.P557= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- PCDHGA7 | c.2121C>T p.F707= | Silent (SNP) | VAF 21/391 reads (5%) | catalogued as COSV53941037; called by muse, mutect2
- RGL3 | c.729C>T p.L243= | Silent (SNP) | VAF 26/321 reads (8%) | called by muse, mutect2
- PLOD1 | c.580-243A>G | Intron (SNP) | VAF 32/440 reads (7%) | called by muse, mutect2
- TMEM140 | c.-212T>A | 5'UTR (SNP) | VAF 32/285 reads (11%) | catalogued as rs1438886076; called by muse, mutect2, varscan2
